Somatic mutation profile of tumor specimen TCGA-CN-4739-01A (aliquot TCGA-CN-4739-01A-02D-1512-08) from TCGA case TCGA-CN-4739, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 71.4 years (26,081 days).
Specimen TCGA-CN-4739-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6bec815-c95d-4cb2-9e8b-5a8824f3e8b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4739-10A (Blood Derived Normal), aliquot TCGA-CN-4739-10A-01D-1512-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31d27cfd-93ea-429a-8ccc-8d3b15ffd9a7

The open-access MAF lists 218 somatic variants for this specimen: 163 protein-altering or splice-affecting, 50 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 50, Nonsense Mutation 11, Splice Site 5, Frame Shift Del 3, Intron 3, Frame Shift Ins 2, Splice Region 2, RNA 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NSD1 | c.5129G>C p.C1710S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM043035, COSV100728361, COSV100729547; called by muse, mutect2, varscan2
- RYR2 | c.14695G>A p.D4899N | Missense Mutation (SNP) | VAF 64/308 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs794728807, COSV63711452; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 19/32 reads (59%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10230C>A p.N3410K | Missense Mutation (SNP) | VAF 52/296 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs781106297, COSV101447013; called by muse, mutect2, varscan2
- ADAMTS19 | c.3636G>C p.K1212N | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV99179395; called by muse, mutect2, varscan2
- ADAMTS7 | c.737C>A p.T246N | Missense Mutation (SNP) | VAF 13/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1395548336, COSV101183161; called by muse, mutect2
- ADAMTS9 | c.4048C>T p.R1350W | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758184611, COSV55780071; called by muse, mutect2, varscan2
- ADCK2 | c.1277G>C p.R426P | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as COSV50784796, COSV99301712; called by muse, mutect2, varscan2
- ADGRL2 | c.2767G>A p.A923T (on ENST00000370717 / NM_001366005.1; = p.A910T on NM_012302.4) | Missense Mutation (SNP) | VAF 85/377 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV99590011; called by muse, mutect2, varscan2
- ANKRD40 | c.266T>C p.I89T | Missense Mutation (SNP) | VAF 53/200 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99560549; called by muse, mutect2, varscan2
- ANKRD52 | c.562G>T p.V188F | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99921432; called by muse, mutect2, varscan2
- APAF1 | c.869A>G p.K290R (on ENST00000551964 / NM_181861.2; = p.K279R on NM_001160.3) | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV100244208; called by muse, mutect2, varscan2
- ARHGAP31 | c.4289G>A p.R1430Q | Missense Mutation (SNP) | VAF 10/124 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761090674, COSV51800267; called by muse, mutect2
- ASPG | c.364G>A p.A122T | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.048); catalogued as rs941045891, COSV101496426; called by muse, mutect2, varscan2
- ATRNL1 | c.3420G>T p.S1140= | Splice Region (SNP) | VAF 16/106 reads (15%) | catalogued as COSV58074963, COSV58099812; called by muse, varscan2
- ATXN2L | c.796G>T p.V266L | Missense Mutation (SNP) | VAF 24/109 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100294699; called by muse, mutect2, varscan2
- BMP8B | c.921C>A p.Y307* | Nonsense Mutation (SNP) | VAF 119/198 reads (60%) | catalogued as COSV100735530; called by muse, mutect2, varscan2
- BPNT2 | c.554A>C p.D185A | Missense Mutation (SNP) | VAF 15/411 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV99389130; called by muse, mutect2
- CACNA1C | c.2699C>T p.T900M | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.572); catalogued as rs1027676345, COSV59699692; called by muse, mutect2, varscan2
- CCDC186 | c.1444A>T p.K482* | Nonsense Mutation (SNP) | VAF 48/153 reads (31%) | catalogued as COSV100991124; called by muse, mutect2, varscan2
- CDC42EP4 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); catalogued as rs1178686929, COSV100231891; called by muse, mutect2, varscan2
- CDH15 | c.646G>C p.V216L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.205); catalogued as COSV99228606; called by muse, mutect2, varscan2
- CDK14 | c.518G>T p.G173V (on ENST00000380050 / NM_001287135.2; = p.G155V on NM_012395.3) | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV99725976; called by muse, mutect2, varscan2
- CELSR2 | c.6710A>G p.H2237R | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.939); catalogued as COSV99604258; called by muse, mutect2, varscan2
- CFHR5 | c.1375G>C p.D459H | Missense Mutation (SNP) | VAF 62/273 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99889184; called by muse, mutect2, varscan2
- CLEC14A | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 78/267 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.003); catalogued as COSV60561602; called by muse, mutect2, varscan2
- CLPTM1L | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 66/204 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as rs759753432, COSV57992321; called by muse, mutect2, varscan2
- CNST | c.1931G>T p.R644L | Missense Mutation (SNP) | VAF 69/252 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100830250, COSV63624397; called by muse, mutect2, varscan2
- CPQ | c.89A>T p.K30M | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV99613088; called by muse, mutect2, varscan2
- CPXCR1 | c.683G>T p.R228I | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.05); PolyPhen benign (0.381); catalogued as COSV99342277; called by muse, mutect2, varscan2
- CSDE1 | c.1310C>A p.T437N (on ENST00000358528 / NM_001007553.3; = p.T406N on NM_007158.6) | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.202); catalogued as COSV54743507, COSV99795359; called by muse, mutect2
- CSMD3 | c.6023G>T p.S2008I (on ENST00000297405 / NM_001363185.1; = p.S1904I on NM_052900.3) | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV99838832; called by muse, mutect2, varscan2
- CSNK2A1 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 17/93 reads (18%) | catalogued as COSV53934392; called by muse, mutect2, varscan2
- DCBLD2 | c.1717G>C p.A573P | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.399); catalogued as COSV100472650; called by muse, mutect2, varscan2
- DDX60 | c.4429C>G p.Q1477E | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs751155591, COSV101190516, COSV67096420; called by muse, mutect2, varscan2
- DMBX1 | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100760827; called by muse, mutect2, varscan2
- DNAAF1 | c.541A>T p.S181C | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.591); catalogued as COSV100533733; called by muse, mutect2, varscan2
- DPPA2 | c.305A>G p.D102G | Missense Mutation (SNP) | VAF 18/604 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV101524779; called by muse, mutect2
- DTNA | c.91C>T p.R31* | Nonsense Mutation (SNP) | VAF 8/100 reads (8%) | catalogued as rs1320555032, COSV51994365; called by muse, mutect2
- DZIP1 | c.1742G>A p.R581K (on ENST00000347108; = p.R562K on NM_014934.5) | Missense Mutation (SNP) | VAF 52/162 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as COSV100714038; called by muse, mutect2, varscan2
- ELMO1 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100165030; called by muse, mutect2, varscan2
- EPHA3 | c.2812A>G p.S938G | Missense Mutation (SNP) | VAF 29/158 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.987); catalogued as rs754599782, COSV100346520; called by muse, mutect2, varscan2
- ERAL1 | c.711+2T>C p.X237_splice | Splice Site (SNP) | VAF 62/222 reads (28%) | catalogued as COSV99650405; called by muse, mutect2, varscan2
- FAM124A | c.703G>A p.D235N (on ENST00000322475 / NM_001242312.2; = p.D271N on NM_145019.4) | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.947); catalogued as rs767755117, COSV54474444; called by muse, mutect2, varscan2
- FAM47B | c.1627C>A p.R543S | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV100264435, COSV61452705; called by muse, mutect2, varscan2
- FGF23 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs753097960, COSV52975359; called by muse, varscan2
- FLG | c.4700G>T p.R1567L | Missense Mutation (SNP) | VAF 100/485 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.254); catalogued as rs372914204, COSV100911731; called by muse, mutect2, varscan2
- FOXP3 | c.1214T>G p.V405G | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); catalogued as COSV100873195; called by muse, mutect2, varscan2
- GAL3ST4 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.474); catalogued as rs377137531; called by muse, mutect2, varscan2
- GIPC3 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100461401; called by muse, mutect2, varscan2
- GPATCH4 | c.619C>G p.P207A | Missense Mutation (SNP) | VAF 31/191 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as COSV100576962; called by muse, mutect2, varscan2
- GPR21 | c.514G>T p.G172* | Nonsense Mutation (SNP) | VAF 46/294 reads (16%) | catalogued as COSV101016478; called by muse, mutect2, varscan2
- GRK2 | c.433C>A p.L145I | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.379); catalogued as COSV100419700; called by muse, mutect2, varscan2
- GRM8 | c.2173T>A p.Y725N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100284149; called by muse, mutect2, varscan2
- H2BC15 | c.149A>G p.H50R | Missense Mutation (SNP) | VAF 100/442 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100357019; called by muse, mutect2, varscan2
- HACE1 | c.860A>G p.Q287R | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.027); catalogued as rs1276986561, COSV99493928; called by muse, mutect2, varscan2
- HDHD5 | c.782C>T p.T261I (on ENST00000336737 / NM_033070.3; = p.T231I on NM_017829.5) | Missense Mutation (SNP) | VAF 85/322 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as COSV99324878; called by muse, mutect2, varscan2
- HELZ2 | c.2798G>A p.R933H (on ENST00000467148 / NM_001037335.2; = p.R364H on NM_033405.3) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as rs1440032448, COSV64410433; called by muse, mutect2, varscan2
- HINFP | c.687C>G p.F229L | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.992); catalogued as COSV100640860; called by muse, mutect2, varscan2
- IFNA16 | c.555A>T p.L185F | Missense Mutation (SNP) | VAF 103/368 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.701); catalogued as rs1368220629, COSV101207073; called by muse, mutect2, varscan2
- IGSF1 | c.1194G>A p.W398* | Nonsense Mutation (SNP) | VAF 52/101 reads (51%) | catalogued as COSV63836039; called by muse, mutect2, varscan2
- IQCC | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 60/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99356686; called by muse, mutect2, varscan2
- ITM2A | c.685C>A p.R229S | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV100964472, COSV64810539; called by muse, mutect2, varscan2
- JAK1 | c.620A>T p.Q207L | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as COSV61090426; called by muse, mutect2, varscan2
- KCNF1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs762076343, COSV99705783; called by muse, mutect2, varscan2
- KIAA0319 | c.360G>C p.M120I | Missense Mutation (SNP) | VAF 74/154 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100985665; called by muse, mutect2, varscan2
- KIF4A | c.1324G>T p.A442S | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.772); catalogued as COSV100979578; called by muse, mutect2, varscan2
- KIF6 | c.449A>G p.N150S | Missense Mutation (SNP) | VAF 49/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754642153, COSV99759529; called by muse, mutect2, varscan2
- KTI12 | c.59A>G p.E20G | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV100860216; called by muse, mutect2, varscan2
- LIFR | c.2501T>A p.V834E | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV99664688; called by muse, mutect2, varscan2
- LRP1B | c.11186G>C p.C3729S | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101257987, COSV67232709; called by muse, mutect2, varscan2
- LRP1B | c.7261T>A p.S2421T | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101257988; called by muse, mutect2, varscan2
- LRRC4B | c.1072C>A p.H358N | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100975981; called by muse, mutect2, varscan2
- MAB21L2 | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.963); catalogued as COSV100462270; called by muse, mutect2, varscan2
- MCM2 | c.2026G>A p.A676T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1016595789, COSV54034494, COSV99413258; called by muse, mutect2
- MEP1A | c.2219T>C p.L740P | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.26); catalogued as COSV100042881; called by muse, mutect2, varscan2
- MIS18BP1 | c.676C>G p.Q226E | Missense Mutation (SNP) | VAF 39/153 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100173100; called by muse, mutect2, varscan2
- MMRN1 | c.2641A>T p.K881* | Nonsense Mutation (SNP) | VAF 9/80 reads (11%) | catalogued as rs377087842; called by muse, mutect2, varscan2
- MORC1 | c.1721T>C p.V574A | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99226766; called by muse, mutect2, varscan2
- MRC2 | c.2838G>T p.L946F | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100316423; called by muse, mutect2, varscan2
- MTA1 | c.1626G>A p.E542= | Splice Region (SNP) | VAF 6/14 reads (43%) | catalogued as rs1459877716, COSV100495307; called by muse, mutect2, varscan2
- MTO1 | c.1526G>T p.R509L (on ENST00000370300 / NM_133645.3; = p.R484L on NM_012123.4) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100940461, COSV64773654; called by muse, mutect2, varscan2
- MUC16 | c.24464G>T p.R8155M | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV101200367, COSV67482088; called by muse, mutect2, varscan2
- NAV1 | c.3172G>A p.G1058S | Missense Mutation (SNP) | VAF 14/185 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs755667365, COSV99819115, COSV99819132; called by muse, mutect2
- NAV3 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as COSV99892882; called by muse, mutect2, varscan2
- NEK6 | c.515-1G>A p.X172_splice | Splice Site (SNP) | VAF 110/384 reads (29%) | catalogued as COSV100207003; called by muse, mutect2, varscan2
- NPAP1 | c.1306C>A p.P436T | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.943); catalogued as rs1232098324, COSV100275642; called by muse, mutect2, varscan2
- NSUN5 | c.143C>G p.A48G | Missense Mutation (SNP) | VAF 25/114 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as COSV99392463; called by muse, mutect2, varscan2
- NT5C2 | c.482-2A>G p.X161_splice | Splice Site (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100583599; called by muse, mutect2, varscan2
- NUDT21 | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV100273101; called by muse, mutect2
- OLFM3 | c.832G>T p.G278W (on ENST00000338858 / NM_001288821.1; = p.G258W on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100129762; called by muse, mutect2
- OR1B1 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 20/92 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.026); catalogued as COSV100506400, COSV100506500, COSV59172494; called by muse, mutect2, varscan2
- OR2K2 | c.205T>A p.L69M (on ENST00000374428; = p.L40M on NM_205859.2) | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100235374; called by muse, mutect2, varscan2
- OR5D13 | c.554T>C p.V185A | Missense Mutation (SNP) | VAF 32/253 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100686936; called by muse, mutect2, varscan2
- OR8J1 | c.620T>C p.V207A | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV100275082; called by muse, mutect2, varscan2
- OTOGL | c.2094C>G p.Y698* (on ENST00000547103; = p.Y689* on NM_173591.4 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 81/303 reads (27%) | catalogued as COSV101509388; called by muse, mutect2, varscan2
- OTUD7B | c.2398A>T p.T800S | Missense Mutation (SNP) | VAF 76/305 reads (25%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.01); catalogued as COSV100967623; called by muse, mutect2, varscan2
- PALD1 | c.127T>A p.L43M | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV99698444; called by muse, mutect2, varscan2
- PCDH11X | c.2825C>A p.A942D | Missense Mutation (SNP) | VAF 80/180 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as COSV100012874; called by muse, mutect2, varscan2
- PCDHB5 | c.556G>A p.G186R | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.035); catalogued as COSV50654580, COSV50661768; called by muse, mutect2, varscan2
- PDK4 | c.463C>T p.L155F | Missense Mutation (SNP) | VAF 42/192 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs572718482, COSV99138873; called by muse, mutect2, varscan2
- PDS5B | c.3394G>C p.G1132R | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as COSV100221166; called by muse, mutect2
- PDZD2 | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 38/233 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.398); catalogued as rs868658983, COSV99225641; called by muse, mutect2, varscan2
- PDZD2 | c.893A>C p.D298A | Missense Mutation (SNP) | VAF 39/236 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV99225643; called by muse, mutect2, varscan2
- PDZRN3 | c.1731C>A p.S577R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV55198204; called by muse, mutect2, varscan2
- PI15 | c.281A>G p.D94G | Missense Mutation (SNP) | VAF 67/308 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.335); catalogued as COSV99478106; called by muse, varscan2
- PIK3CA | c.1088G>C p.G363A | Missense Mutation (SNP) | VAF 56/260 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs759188876, COSV55916105; called by muse, mutect2, varscan2
- PKD1 | c.2446G>T p.D816Y | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.102); catalogued as COSV99238448; called by muse, mutect2, varscan2
- PKHD1L1 | c.1244C>A p.A415D | Missense Mutation (SNP) | VAF 16/282 reads (6%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.525); catalogued as COSV101006499, COSV65740512; called by muse, mutect2
- PLCB4 | c.2671T>A p.S891T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.021); catalogued as COSV99596018; called by muse, mutect2
- PLEKHA4 | c.2147A>C p.Q716P | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99612798; called by muse, mutect2, varscan2
- PMFBP1 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 94/376 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99401164; called by muse, mutect2, varscan2
- PNLIPRP1 | c.496C>T p.H166Y | Missense Mutation (SNP) | VAF 113/485 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs782603902, COSV100724451; called by muse, mutect2, varscan2
- PPFIA2 | c.1193A>T p.Q398L | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV100334320; called by muse, mutect2, varscan2
- PPP1R12C | c.1514C>T p.P505L | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs369559413, COSV54739644; called by muse, mutect2, varscan2
- PPP1R26 | c.946G>T p.E316* | Nonsense Mutation (SNP) | VAF 22/159 reads (14%) | catalogued as COSV100778106; called by muse, mutect2, varscan2
- PXDNL | c.3065T>G p.L1022R | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100684696; called by muse, mutect2
- PYHIN1 | c.196A>G p.I66V | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100932372; called by muse, mutect2, varscan2
- RP1L1 | c.3573G>C p.E1191D | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as COSV101223396; called by muse, mutect2, varscan2
- RYBP | c.79G>T p.E27* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV101523277, COSV72180790; called by muse, mutect2
- RYR1 | c.5473C>T p.H1825Y | Missense Mutation (SNP) | VAF 66/244 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); catalogued as COSV100616205; called by muse, mutect2, varscan2
- SELP | c.748T>A p.W250R | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99740370; called by muse, mutect2, varscan2
- SH3KBP1 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV101114934; called by mutect2, varscan2
- SHANK2 | c.4748C>T p.P1583L | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.965); catalogued as rs1057228974; called by muse, mutect2, varscan2
- SHE | c.1181+2T>A p.X394_splice | Splice Site (SNP) | VAF 37/187 reads (20%) | catalogued as COSV100496099; called by muse, mutect2, varscan2
- SI | c.5390C>T p.P1797L | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV52267643; called by muse, mutect2, varscan2
- SLC5A8 | c.1099G>T p.D367Y | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101610568, COSV73310877; called by muse, mutect2, varscan2
- SLC8A1 | c.2350T>C p.F784L | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV60479495; called by muse, mutect2, varscan2
- SLFN5 | c.527T>G p.F176C | Missense Mutation (SNP) | VAF 70/253 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770925097, COSV100249728; called by muse, mutect2, varscan2
- SLIT2 | c.4042C>A p.P1348T | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV99885112; called by muse, mutect2, varscan2
- SMARCAD1 | c.1873G>C p.A625P | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100758974, COSV62773721; called by muse, mutect2, varscan2
- SOX7 | c.395del p.G132Afs*4 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | catalogued as COSV58730721; called by mutect2, pindel
- ST18 | c.288G>T p.M96I | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV52483136, COSV52507618; called by muse, mutect2, varscan2
- ST3GAL3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 76/402 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as COSV99495619; called by muse, varscan2
- ST3GAL3 | c.4G>T p.G2* | Nonsense Mutation (SNP) | VAF 87/421 reads (21%) | catalogued as COSV99495621; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.457G>A p.V153M | Missense Mutation (SNP) | VAF 6/33 reads (18%) | PolyPhen probably damaging (0.999); catalogued as rs778839685, COSV56572853; called by muse, mutect2, varscan2
- SVIL | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.078); catalogued as COSV100881389; called by muse, mutect2, varscan2
- TAF1 | c.3596A>G p.E1199G (on ENST00000373790 / NM_138923.4; = p.E1220G on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52108178; called by muse, mutect2, varscan2
- TMEM229B | c.449C>A p.P150H | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.431); catalogued as COSV100664343; called by muse, mutect2, varscan2
- TMTC1 | c.946A>G p.T316A (on ENST00000539277 / NM_001193451.2; = p.T208A on NM_175861.3) | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV99760146; called by muse, mutect2
- TOGARAM1 | c.32T>A p.L11Q | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.779); catalogued as COSV100753165; called by muse, mutect2, varscan2
- TRAPPC11 | c.3377A>G p.D1126G | Missense Mutation (SNP) | VAF 30/328 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.054); catalogued as COSV100591943; called by muse, mutect2
- TTC17 | c.3151-2A>T p.X1051_splice | Splice Site (SNP) | VAF 128/423 reads (30%) | catalogued as COSV99235549; called by muse, mutect2, varscan2
- UCK1 | c.546G>C p.Q182H | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV100944120; called by muse, mutect2, varscan2
- ULK4 | c.3544A>G p.I1182V | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs924366193, COSV100093542; called by muse, mutect2, varscan2
- VNN1 | c.567T>A p.N189K | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100907772; called by muse, mutect2, varscan2
- WDR24 | c.392G>T p.R131L (on ENST00000248142; = p.R69L on NM_032259.4) | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as COSV50197153, COSV99555842; called by muse, mutect2, varscan2
- WRN | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV99989379; called by muse, mutect2, varscan2
- XIRP2 | c.5256G>T p.R1752S (on ENST00000628543; = p.R1927S on NM_152381.6) | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.476); catalogued as COSV54718552, COSV99744756; called by muse, mutect2, varscan2
- XKR7 | c.1026G>T p.W342C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101629274; called by muse, mutect2
- XPR1 | c.697A>T p.T233S | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.599); catalogued as rs754431319, COSV100851491; called by muse, mutect2, varscan2
- YARS2 | c.983A>T p.E328V | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); catalogued as COSV100256459; called by muse, mutect2, varscan2
- ZNF135 | c.1632C>A p.H544Q (on ENST00000313434 / NM_001289401.2; = p.H556Q on NM_003436.4) | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100536701; called by muse, mutect2, varscan2
- ZNF440 | c.1034G>A p.C345Y | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV100407619; called by muse, mutect2, varscan2
- ZNF536 | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.685); catalogued as COSV62825903; called by muse, mutect2, varscan2
- ZNF695 | c.4G>A p.G2R | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100377583; called by muse, mutect2, varscan2
- ZNF75D | c.836A>T p.K279I | Missense Mutation (SNP) | VAF 46/92 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); catalogued as COSV100883670; called by muse, mutect2, varscan2
- ASB16 | c.574_575del p.A192Qfs*67 | Frame Shift Del (DEL) | VAF 36/190 reads (19%) | called by pindel, varscan2
- FGF23 | c.708dup p.G237Wfs*25 | Frame Shift Ins (INS) | VAF 24/150 reads (16%) | called by pindel, varscan2
- FPR1 | c.717del p.L240Yfs*24 | Frame Shift Del (DEL) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- IGHG1 | c.622A>T p.N208Y | Missense Mutation (SNP) | VAF 47/430 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PARP14 | c.4696dup p.T1566Nfs*3 | Frame Shift Ins (INS) | VAF 26/174 reads (15%) | called by mutect2, varscan2
- TRGJP | c.12G>T p.L4F | Missense Mutation (SNP) | VAF 68/308 reads (22%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA10 | c.150T>C p.F50= | Silent (SNP) | VAF 99/211 reads (47%) | catalogued as COSV99288888; called by muse, mutect2, varscan2
- ABCA7 | c.363G>T p.T121= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV99566213; called by muse, mutect2, varscan2
- ANKRD2 | c.957G>C p.L319= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV100080940; called by muse, mutect2, varscan2
- ATM | c.4314T>C p.I1438= | Silent (SNP) | VAF 10/117 reads (9%) | catalogued as COSV99590402; called by muse, mutect2
- C9 | c.222T>C p.N74= | Silent (SNP) | VAF 34/98 reads (35%) | catalogued as rs1290539249, COSV99662226; called by muse, mutect2, varscan2
- CCDC116 | c.1041G>A p.P347= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs749242831, COSV53039650; called by muse, mutect2, varscan2
- CCDC42 | c.513G>T p.V171= | Silent (SNP) | VAF 5/69 reads (7%) | catalogued as COSV99549833; called by muse, mutect2
- CDH10 | c.2124G>T p.T708= | Silent (SNP) | VAF 42/212 reads (20%) | catalogued as COSV100052096, COSV52573235; called by muse, mutect2, varscan2
- CDR1 | c.36C>T p.D12= | Silent (SNP) | VAF 65/123 reads (53%) | catalogued as rs777604320, COSV65164577; called by muse, mutect2, varscan2
- CFAP45 | c.978A>G p.K326= | Silent (SNP) | VAF 53/228 reads (23%) | catalogued as COSV100928621, COSV63648466; called by muse, mutect2, varscan2
- CFHR5 | c.1287T>A p.I429= | Silent (SNP) | VAF 35/114 reads (31%) | catalogued as COSV99889181; called by muse, mutect2, varscan2
- CRB1 | c.2292T>A p.R764= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV100957956; called by muse, mutect2, varscan2
- CYTIP | c.537G>A p.Q179= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV99938793; called by muse, mutect2, varscan2
- DIRAS1 | c.405G>C p.A135= | Silent (SNP) | VAF 27/115 reads (23%) | catalogued as COSV100053079, COSV60216459; called by muse, mutect2, varscan2
- DTX1 | c.399C>T p.Y133= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV99986306; called by muse, mutect2
- ELFN2 | c.2370C>T p.H790= | Silent (SNP) | VAF 10/159 reads (6%) | catalogued as rs148494870; called by muse, mutect2
- EMC8 | c.261C>T p.Y87= | Silent (SNP) | VAF 15/186 reads (8%) | catalogued as rs146555773; called by muse, mutect2
- ERG | c.1338C>T p.P446= (on ENST00000398919 / NM_001243428.1; = p.P422= on NM_004449.4) | Silent (SNP) | VAF 19/62 reads (31%) | catalogued as rs200220847, COSV99902284; called by muse, mutect2, varscan2
- ETNPPL | c.84G>A p.S28= | Silent (SNP) | VAF 60/200 reads (30%) | catalogued as rs748968101, COSV56597460; called by muse, mutect2, varscan2
- GMPPA | c.648G>A p.G216= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV100354722; called by muse, mutect2
- GPR141 | c.90C>T p.G30= | Silent (SNP) | VAF 57/221 reads (26%) | catalogued as rs368456046; called by muse, mutect2, varscan2
- HERC4 | c.2601A>T p.T867= (on ENST00000395198 / NM_022079.3; = p.T859= on NM_015601.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 50/229 reads (22%) | catalogued as COSV99517165; called by muse, mutect2, varscan2
- IFT80 | c.315C>T p.H105= | Silent (SNP) | VAF 92/287 reads (32%) | catalogued as CM074277, COSV100424894; called by muse, mutect2, varscan2
- IGF1R | c.2766C>T p.F922= | Silent (SNP) | VAF 21/126 reads (17%) | catalogued as rs1178228490, COSV51281068; called by muse, mutect2, varscan2
- KCNV2 | c.483C>G p.V161= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs1239404643, COSV101172622; called by muse, mutect2, varscan2
- LRP1B | c.3870A>T p.T1290= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as COSV101257989; called by muse, mutect2, varscan2
- MAGI1 | c.3300C>T p.T1100= (on ENST00000402939 / NM_001033057.2; = p.T1129= on NM_004742.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/135 reads (22%) | catalogued as COSV100441793; called by muse, mutect2, varscan2
- NLRP8 | c.879T>A p.S293= | Silent (SNP) | VAF 54/300 reads (18%) | catalogued as COSV99405557; called by muse, mutect2, varscan2
- NOD2 | c.3012G>T p.L1004= | Silent (SNP) | VAF 14/78 reads (18%) | catalogued as COSV100318695; called by muse, mutect2, varscan2
- NPSR1 | c.252C>T p.T84= | Silent (SNP) | VAF 39/171 reads (23%) | catalogued as COSV100706668; called by muse, mutect2, varscan2
- OLFM3 | c.834G>T p.G278= (on ENST00000338858 / NM_001288821.1; = p.G258= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 28/152 reads (18%) | catalogued as COSV100129759; called by muse, mutect2
- OR5D13 | c.555A>T p.V185= | Silent (SNP) | VAF 33/255 reads (13%) | catalogued as COSV100686937; called by muse, mutect2, varscan2
- PAX3 | c.583C>A p.R195= | Silent (SNP) | VAF 23/219 reads (11%) | catalogued as rs1220219700, CM973769, COSV99286679; called by muse, mutect2, varscan2
- PDZRN4 | c.1497G>A p.R499= (on ENST00000402685 / NM_001164595.2; = p.R241= on NM_013377.4) | Silent (SNP) | VAF 21/104 reads (20%) | catalogued as COSV54200239; called by muse, mutect2, varscan2
- PLD5 | c.999A>T p.I333= (on ENST00000442594; = p.I271= on NM_001195811.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 52/183 reads (28%) | catalogued as COSV100141212; called by muse, mutect2, varscan2
- PPP2R2B | c.849G>T p.S283= (on ENST00000394409; = p.S349= on NM_181674.2) | Silent (SNP) | VAF 46/117 reads (39%) | catalogued as rs748939898, COSV100355257, COSV60755031; called by muse, mutect2, varscan2
- RBBP6 | c.2853A>T p.P951= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100154707; called by muse, mutect2, varscan2
- RETSAT | c.34C>T p.L12= | Silent (SNP) | VAF 38/125 reads (30%) | catalogued as rs962551857, COSV55526550; called by muse, varscan2
- RNLS | c.555G>A p.L185= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100076699; called by muse, mutect2, varscan2
- RP1 | c.4368A>G p.T1456= | Silent (SNP) | VAF 37/157 reads (24%) | catalogued as COSV99608059; called by muse, mutect2, varscan2
- RPGRIP1L | c.822G>A p.Q274= | Silent (SNP) | VAF 10/144 reads (7%) | catalogued as COSV100046513; called by muse, mutect2
- SLCO6A1 | c.924A>G p.P308= | Silent (SNP) | VAF 43/142 reads (30%) | catalogued as COSV101134598; called by muse, mutect2, varscan2
- TCAIM | c.1080C>T p.H360= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as rs753759285, COSV100703317; called by muse, mutect2, varscan2
- TECTA | c.3825C>A p.T1275= | Silent (SNP) | VAF 53/234 reads (23%) | catalogued as rs750122360, COSV99880420; called by muse, mutect2, varscan2
- TFB2M | c.1083A>G p.K361= | Silent (SNP) | VAF 8/120 reads (7%) | catalogued as COSV100830482; called by muse, mutect2
- TLE2 | c.1101G>T p.V367= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99504493; called by muse, mutect2, varscan2
- TMIGD2 | c.582C>T p.N194= | Silent (SNP) | VAF 34/194 reads (18%) | catalogued as rs764257256, COSV100010370; called by muse, mutect2
- TUBB6 | c.855C>A p.T285= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99302023; called by muse, mutect2, varscan2
- USP2 | c.321C>A p.L107= | Silent (SNP) | VAF 35/273 reads (13%) | catalogued as COSV99489782; called by muse, varscan2
- VPS35L | c.732C>G p.L244= | Silent (SNP) | VAF 22/131 reads (17%) | catalogued as COSV99221151, COSV99221749; called by muse, mutect2, varscan2
- BAGE2 | n.199G>T | RNA (SNP) | VAF 24/128 reads (19%) | called by muse, varscan2
- CTBP2 | c.58+12107C>A | Intron (SNP) | VAF 21/108 reads (19%) | catalogued as COSV100456626; called by muse, mutect2, varscan2
- HERC2P3 | n.1714C>T | RNA (SNP) | VAF 18/144 reads (13%) | called by muse, mutect2, varscan2
- NACA | c.71-3563C>T | Intron (SNP) | VAF 33/131 reads (25%) | catalogued as COSV100771433; called by muse, mutect2, varscan2
- ZNF493 | c.-132+7863G>A | Intron (SNP) | VAF 38/152 reads (25%) | catalogued as COSV100372017; called by muse, varscan2
